TCGA case TCGA-AG-A02N — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ad1c98b-5395-477e-87a8-19dff3a59c26

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 67.6 years (24,687 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,885 days (5.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin Calcium; Days to treatment start: 28 days; Days to treatment end: 89 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 59 days; Days to treatment end: 89 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.

Follow-up (1 entry)
- Days to follow up: 1,885 days (5.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.07 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-A02N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 310 mg.
  Slide TCGA-AG-A02N-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-AG-A02N-01A-01-MS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 13; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-AG-A02N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AG-A02N-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-AG-A02N-11A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.
  Slide TCGA-AG-A02N-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2.07; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Pharmaceutical therapy drug name: Folinic acid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,885 days; disease-specific survival: no event (censored), 1,885 days; progression-free interval: no event (censored), 1,885 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AG-A02N-01A-11D-A080-01): tumor purity 0.83, ploidy 2.11, whole-genome doublings 0.
